Somatic mutation profile of tumor specimen 0DII47 from CCDI case PBBVND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 8.5 years (3,110 days).
Specimen 0DII47: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 957efde9-2aa8-4238-86e5-748ffaa4b478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII38 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9555e8b0-3c1d-41d0-824a-3a8f6046c65a

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELF5 | c.1012T>G p.Y338D | Missense Mutation (SNP) | VAF 16/580 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- NSDHL | c.1083G>T p.R361S | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2
- AHI1 | c.*98A>G | 3'UTR (SNP) | VAF 24/602 reads (4%) | called by muse, mutect2
